Somatic mutation profile of tumor specimen C3N-01214-02 (aliquot CPT0075550012) from CPTAC case C3N-01214, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 60.9 years (22,241 days).
Specimen C3N-01214-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 812ebc69-f2ca-43dc-b8e9-984e34e7cd32.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01214-71 (Blood Derived Normal), aliquot CPT0075620002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/446fa917-b05e-4ee3-9f5e-2f80d2151c12

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4, Splice Region 2, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCAS3 | c.1732G>T p.E578* (on ENST00000390652 / NM_001353144.2; = p.E563* on NM_017679.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/307 reads (6%) | catalogued as COSV66775862; called by muse, mutect2
- FAM197Y1 | n.356C>T | Splice Region (SNP) | VAF 18/280 reads (6%) | catalogued as rs1326027153; called by muse, mutect2
- ANPEP | c.658T>C p.S220P | Missense Mutation (SNP) | VAF 17/338 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2
- BPHL | c.329C>G p.P110R | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- PCDHB1 | c.924T>G p.D308E | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PPP1R3C | c.858A>T p.L286F | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- RP9 | c.183+8T>A | Splice Region (SNP) | VAF 17/354 reads (5%) | called by muse, mutect2
- SRSF7 | c.462-1G>T p.X154_splice | Splice Site (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- TECRL | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 13/320 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.038); called by muse, mutect2
- TNPO3 | c.2552C>T p.P851L | Missense Mutation (SNP) | VAF 15/287 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.391); called by muse, mutect2
- TNS4 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- TOP2B | c.1082T>A p.V361E (on ENST00000264331 / NM_001330700.2; = p.V356E on NM_001068.3) | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.176); called by muse, mutect2
- UGT3A2 | c.530T>C p.L177P | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); called by muse, mutect2
- UTY | c.3544A>G p.N1182D | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, mutect2
- ATXN3L | c.639A>G p.S213= | Silent (SNP) | VAF 9/116 reads (8%) | called by muse, mutect2
- DCAF12L2 | c.519C>T p.S173= | Silent (SNP) | VAF 12/210 reads (6%) | catalogued as rs1254419741, COSV104418638; called by muse, mutect2
- RBM10 | c.156G>A p.E52= | Silent (SNP) | VAF 8/122 reads (7%) | catalogued as rs781831956; called by muse, mutect2
- TNS4 | c.1023C>T p.T341= | Silent (SNP) | VAF 14/310 reads (5%) | called by muse, mutect2
